Somatic mutation profile of tumor specimen TARGET-20-PASCBW-09A (aliquot TARGET-20-PASCBW-09A-01D) from TARGET case TARGET-20-PASCBW, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.8 years (5,416 days).
Specimen TARGET-20-PASCBW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 712578ee-a327-4cb6-afc1-bb402ed1cf6c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASCBW-14A (Bone Marrow Normal), aliquot TARGET-20-PASCBW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/506f8b74-1d2b-4510-b8bb-d5cd676039a7

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 2, Frame Shift Ins 2, Frame Shift Del 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 41/207 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121918468, CM043335, CM096577, COSV100692090, COSV61005148; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCATG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 25/76 reads (33%) | catalogued as rs1554138188, COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, pindel, varscan2
- TET2 | c.1336_1337del p.L446Kfs*8 | Frame Shift Del (DEL) | VAF 109/358 reads (30%) | called by mutect2, pindel, varscan2
- TET2 | c.2763dup p.H922Tfs*2 | Frame Shift Ins (INS) | VAF 122/346 reads (35%) | called by mutect2, pindel, varscan2
- KIT | c.*1231T>C | 3'UTR (SNP) | VAF 214/415 reads (52%) | catalogued as rs1224603317; called by muse, mutect2, varscan2
- TPR | c.*182T>C | 3'UTR (SNP) | VAF 103/242 reads (43%) | catalogued as rs758273870; called by muse, mutect2, varscan2
